Surgical pathology report (de-identified scan), TCGA case TCGA-KD-A5QU, project TCGA-SARC (Sarcoma), tissue source site Mount Sinai School of Medicine, specimen TCGA-KD-A5QU-01A (Primary Tumor).

ICD-0-3

Leiomyosarcoma, NOS 8890/3
Site: Uterus, NOS C55.9

Leiomyosarcoma

CATEGORY: SARCOMA—LEIOMYOSARCOMA

hw 3/29/13

FROM PRIMARY GYNECOLOGIC SURGERY

CLINICAL HISTORY - Uterine CA.

UTERUS, CERVIX, BIL. TUBES AND OVARIES (440g) - Uterine leiomyosarcoma, high-grade, 9cm diameter. The tumor shows vascular space invasion and penetrates the uterine wall to within 1.5mm of the serosa. However, serosa and parametrial edges are free of tumor.

Proliferative endometrium. Parakeratotic cervix. Ovaries with physiologic changes. Fallopian tubes with edema. Histological note: The tumor shows coagulative necrosis, severe nuclear atypia, and mitotic rate approaching 50 mitotic figures per 10 high-power fields.

OMENTUM - Benign omental tissue in several random sections.

RIGHT COMMON ILIAC LYMPH NODE - One benign lymph node.

RIGHT COMMON LYMPH NODE - One benign lymph node.

RIGHT OBTURATOR LYMPH NODE - One benign lymph node.

LEFT PELVIC LYMPH NODE - Benign blood vessel. No lymph nodes identified.

LEFT OBTURATOR LYMPH NODE - One benign lymph node.

Diagnosis Discrepancy	hw 2/8/13	/

Source: NCI Genomic Data Commons file c57d3829-e3b6-4c9a-b7e7-2db8c5982424 (TCGA-KD-A5QU.C273AC50-29E3-4568-A7F2-15FB5F57BFD9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).